Somatic mutation profile of tumor specimen BA3028D (aliquot aq-BA3028D) from BEATAML1.0 case 2362, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,950 days).
Specimen BA3028D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 146cd1ed-bf9f-46fd-a696-da3de6e9ded5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2536D (Solid Tissue Normal), aliquot aq-BA2536D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d3374ad-235a-4bb0-8c45-bac74e0a02b9

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'UTR 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLITRK4 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs143575705, COSV62022218; called by muse, mutect2
- TMEM260 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55097507; called by muse, mutect2
- CARNS1 | c.1798C>A p.L600M | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LCT | c.1632G>T p.W544C | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAST1 | c.3776C>A p.P1259Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRTFA | c.2260G>T p.A754S | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2
- NSMCE1 | c.715A>C p.I239L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, varscan2
- STK11IP | c.1775C>A p.P592Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2
- ATP2A3 | c.1230G>T p.L410= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ARMCX4 | c.1038+2735G>A | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- PIM1 | c.-28T>G | 5'UTR (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- SRGN | c.-1C>A | 5'UTR (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
